Somatic mutation profile of tumor specimen TCGA-09-0369-01A (aliquot TCGA-09-0369-01A-01W-0371-08) from TCGA case TCGA-09-0369, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.7 years (20,705 days).
Specimen TCGA-09-0369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0b6ce43-1b4f-421b-904a-be03fdbfc91b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-0369-10C (Blood Derived Normal), aliquot TCGA-09-0369-10C-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d13430ee-e65c-46c5-a468-21f3863b535f

The open-access MAF lists 83 somatic variants for this specimen: 65 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Nonsense Mutation 5, Splice Site 3, 3'Flank 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 132/145 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 50/316 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99574347; called by muse, varscan2
- ABL2 | c.1843C>T p.Q615* (on ENST00000502732 / NM_007314.4; = p.Q600* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 38/584 reads (7%) | catalogued as COSV100772534; called by muse, mutect2
- ACBD4 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as rs1345554276, COSV58851391; called by muse, mutect2, varscan2
- ADAMTS14 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941953, COSV64601045; called by muse, mutect2, varscan2
- ANO2 | c.606A>C p.K202N (on ENST00000356134 / NM_001278597.3; = p.K206N on NM_001278596.3) | Missense Mutation (SNP) | VAF 211/428 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59015586; called by muse, mutect2, varscan2
- AOC2 | c.1894C>T p.Q632* (on ENST00000253799 / NM_009590.4; = p.Q605* on NM_001158.5) | Nonsense Mutation (SNP) | VAF 69/164 reads (42%) | catalogued as rs970881126, COSV53825593; called by muse, mutect2, varscan2
- AOX1 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as COSV101021801; called by muse, mutect2
- AP1M1 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs372560384, COSV52225827; called by muse, mutect2, varscan2
- ATP6V1D | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as rs771168394, COSV53599217, COSV99371030; called by muse, mutect2, varscan2
- CAD | c.2467G>C p.V823L | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV53025299; called by muse, mutect2, varscan2
- CCNB1IP1 | c.504T>A p.N168K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV62302603; called by muse, mutect2, varscan2
- CELSR3 | c.2245G>A p.V749I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs145148789; called by muse, mutect2, varscan2
- CERS3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 96/113 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767763454, COSV52566792; called by muse, mutect2, varscan2
- CLGN | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57773946; called by muse, mutect2, varscan2
- CRYBG1 | c.3061C>T p.L1021F | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.308); catalogued as COSV64811561; called by muse, mutect2, varscan2
- CSMD1 | c.9575C>G p.S3192C (on ENST00000520002; = p.S3191C on NM_033225.6) | Missense Mutation (SNP) | VAF 65/297 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59304948; called by muse, mutect2, varscan2
- CSN3 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as rs761442017, COSV59243829; called by muse, mutect2, varscan2
- ETNK2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 63/335 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs751988639, COSV65820560; called by muse, mutect2, varscan2
- FEZF1 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58658470; called by muse, mutect2, varscan2
- FZD7 | c.935G>C p.R312P | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99636919; called by mutect2, varscan2
- GCHFR | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53066782; called by muse, mutect2, varscan2
- GJA1 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV56997507; called by muse, mutect2, varscan2
- GNA12 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV51739921; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 54/89 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56085726; called by muse, mutect2, varscan2
- HENMT1 | c.313A>C p.N105H | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV64230059; called by muse, mutect2, varscan2
- HIVEP2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV99171564; called by muse, mutect2, varscan2
- IL18RAP | c.794T>A p.L265H | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51825243; called by muse, varscan2
- KRT26 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV59415827; called by muse, varscan2
- LAMB4 | c.4480G>C p.V1494L | Missense Mutation (SNP) | VAF 250/609 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV52716821, COSV99224244; called by muse, mutect2, varscan2
- LAMC3 | c.2440G>A p.G814R | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs529385350, COSV100736074, COSV63089922; called by muse, mutect2, varscan2
- LRP5 | c.3798T>A p.C1266* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99591563; called by mutect2, varscan2
- LRRK2 | c.2855T>C p.I952T | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54149107; called by muse, mutect2, varscan2
- MFGE8 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.296); catalogued as COSV51555783; called by muse, mutect2, varscan2
- MGA | c.4139G>A p.R1380Q | Missense Mutation (SNP) | VAF 21/435 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.543); catalogued as rs376715603; called by muse, mutect2
- MRAS | c.407T>G p.I136S | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV56670969; called by muse, mutect2, varscan2
- MYCN | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs775092426, COSV55258248; called by muse, mutect2, varscan2
- MYF5 | c.577+2T>G p.X193_splice | Splice Site (SNP) | VAF 110/286 reads (38%) | catalogued as COSV57354819; called by muse, mutect2, varscan2
- MYOM3 | c.1486+2T>C p.X496_splice | Splice Site (SNP) | VAF 22/232 reads (9%) | catalogued as COSV100292602; called by mutect2, varscan2
- NME8 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 153/255 reads (60%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52248684; called by muse, mutect2, varscan2
- NPHP4 | c.2344C>T p.H782Y | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV100976923; called by muse, mutect2
- OR10A7 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 77/139 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV58278104; called by muse, mutect2, varscan2
- PCDHB11 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1554285402, COSV61310690; called by muse, mutect2, varscan2
- PDZD2 | c.1656T>G p.S552R | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV56855280; called by muse, mutect2, varscan2
- PLXNA1 | c.2989G>A p.G997S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs746458823, COSV99302503; called by muse, varscan2
- PSENEN | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53074314; called by muse, mutect2, varscan2
- PZP | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV54357605; called by muse, mutect2, varscan2
- SCN9A | c.3358A>T p.N1120Y (on ENST00000303354; = p.N1109Y on NM_002977.3) | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV57605636; called by muse, mutect2, varscan2
- SF3B3 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV100209640; called by muse, mutect2, varscan2
- SLC1A7 | c.1414A>T p.I472F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57012395; called by mutect2, varscan2
- SLC25A42 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs749095738, COSV59381563; called by muse, mutect2, varscan2
- SOS2 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.135); catalogued as COSV99365546; called by muse, mutect2, varscan2
- SUMF2 | c.802C>T p.R268C (on ENST00000652303; = p.P297L on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs767327111, COSV51915755; called by muse, mutect2
- SZT2 | c.4807G>A p.V1603I (on ENST00000634258 / NM_001365999.1; = p.V1546I on NM_015284.4) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65168634; called by muse, mutect2, varscan2
- TRA2A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV51716426; called by muse, mutect2, varscan2
- TRAF2 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV56037255; called by muse, mutect2, varscan2
- TRAF3IP3 | c.915+1G>T p.X305_splice | Splice Site (SNP) | VAF 94/338 reads (28%) | catalogued as COSV50551708; called by muse, mutect2, varscan2
- TTN | c.39305G>T p.G13102V (on ENST00000591111; = p.G5678V on NM_003319.4) | Missense Mutation (SNP) | VAF 101/114 reads (89%) | PolyPhen benign (0.011); catalogued as COSV59974093; called by muse, mutect2, varscan2
- UBR5 | c.6659T>A p.V2220E | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99639754; called by muse, mutect2, varscan2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 149/471 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF274 | c.931G>T p.E311* (on ENST00000610905; = p.E206* on NM_016324.3) | Nonsense Mutation (SNP) | VAF 57/483 reads (12%) | catalogued as COSV100464814, COSV58763555; called by muse, mutect2, varscan2
- ZNF512 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV100820698; called by muse, mutect2, varscan2
- FBXO27 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 22/291 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.153); called by muse, mutect2
- TOP2A | c.608_611dup p.M204Ifs*20 | Frame Shift Ins (INS) | VAF 360/850 reads (42%) | called by pindel, varscan2
- TTLL9 | c.1317_*7del | Nonstop Mutation (DEL) | VAF 26/182 reads (14%) | called by mutect2, pindel
- ADCY3 | c.3159C>T p.V1053= | Silent (SNP) | VAF 29/212 reads (14%) | catalogued as rs907824331, COSV99567813; called by muse, varscan2
- AMER1 | c.2631C>T p.G877= | Silent (SNP) | VAF 27/215 reads (13%) | catalogued as COSV57658221; called by muse, mutect2, varscan2
- ATXN2L | c.816C>T p.S272= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as COSV100293894; called by muse, mutect2, varscan2
- CDC25C | c.1342C>A p.R448= | Silent (SNP) | VAF 56/523 reads (11%) | catalogued as COSV100086558; called by muse, mutect2, varscan2
- CDH10 | c.2082G>A p.T694= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as COSV52576436; called by muse, mutect2, varscan2
- CSMD1 | c.4032C>T p.I1344= (on ENST00000520002; = p.I1343= on NM_033225.6) | Silent (SNP) | VAF 17/714 reads (2%) | catalogued as COSV59287481; called by muse, mutect2
- DBF4B | c.1644C>T p.L548= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100154343; called by muse, mutect2
- DCAF4L2 | c.882C>A p.I294= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV100150581; called by muse, mutect2
- DLGAP2 | c.1041C>T p.N347= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as rs759975919, COSV70096666, COSV70097456; called by muse, mutect2, varscan2
- FLNA | c.7734C>T p.F2578= (on ENST00000369850 / NM_001110556.2; = p.F2570= on NM_001456.3) | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100774351; called by muse, mutect2, varscan2
- ILKAP | c.660G>A p.T220= | Silent (SNP) | VAF 57/157 reads (36%) | catalogued as rs150186666, COSV54517839; called by muse, mutect2, varscan2
- ITGAX | c.1017G>A p.T339= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs751433732, COSV51641197, COSV51641897; called by mutect2, varscan2
- NSD2 | c.4000A>C p.R1334= | Silent (SNP) | VAF 29/41 reads (71%) | catalogued as COSV56389009; called by muse, mutect2, varscan2
- PIP4P1 | c.231G>A p.G77= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as COSV99164448; called by muse, mutect2, varscan2
- SAMM50 | c.723G>A p.T241= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs766140123, COSV63110184; called by muse, mutect2, varscan2
- SLC2A9 | c.1083G>T p.G361= | Silent (SNP) | VAF 99/335 reads (30%) | catalogued as rs1432915400, COSV53316233; called by muse, mutect2, varscan2
- SNX15 | c.153G>T p.R51= | Silent (SNP) | VAF 38/113 reads (34%) | catalogued as COSV57246431; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792079 C>A | 3'Flank (SNP) | VAF 24/46 reads (52%) | called by mutect2, varscan2
